Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5501, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5501-01A (Primary Tumor).

PATIENT HISTORY:

The patient is [REDACTED] with a history of PSA value of 2.7 and gastroesophageal reflux. The patient also has a history of biopsy which reveals bilateral poorly differentiated prostatic adenocarcinoma.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

FINAL DIAGNOSIS:

TCGA-EJ-5501

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN EIGHT (8) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN THREE (3) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE $4 + 3 = 7$ WITH TERTIARY PATTERN 5.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.3 CM.
- C. THE CARCINOMA INVOLVES 30% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION.
- E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE ANTERIOR RIGHT MID, POSTERIOR RIGHT MID AND POSTERIOR RIGHT BASE REGIONS (SLIDES 3O, 3U AND 3V).
- F. THE CARCINOMA INVOLVES THE RIGHT SEMINAL VESICLES.
- G. THE LEFT SEMINAL VESICLES ARE FREE OF CARCINOMA.
- H. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- I. EXTENSIVE PERINEURAL INVASION IS IDENTIFIED.
- J. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- K. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- L. PATHOLOGIC TNM STAGE: pT3b N0 MX.
- M. TNM HISTOLOGIC GRADE = G3.
- N. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

PART 4: SOFT TISSUE, LEFT PERIRECTAL FAT, BIOPSY -

BENIGN FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 2.7
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	60%
WEIGHT OF PROSTATE:	48.95gm
TUMOR SIZE:	Maximum dimension: 1.3 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	Yes
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	11
LYMPH NODES POSITIVE:	0
EXTRANODAL EXTENSION:	No
T STAGE, PATHOLOGIC:	pT3b
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 4b2fbec8-cfa0-4c0b-a736-51209c79c6ea (TCGA-EJ-5501.630DEE46-15DB-4A16-84EE-A9D25FCCCB80.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).